MMRF case MMRF_1331 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/62d34e48-70e6-49be-a94e-390d2de2181e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.1 years (24,883 days); ISS stage: III; Days to last known disease status: 324 days; Days to last follow up: 324 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 102 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 324.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 6.2 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 242 µmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL.
- Day 99 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 19 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 6.22 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 269 µmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL.
- Day 165 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 5.64 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 234 µmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL.
- Day 284 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 24.1 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 241 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 4.07 mmol/L.

Other clinical attributes
- Day -3: Weight: 86 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1331_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1331_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
